MMRF case MMRF_2200 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b1c7db25-0db6-4ebe-954a-c9c6aae39e88

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 449 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,385 days); ISS stage: III; Days to last known disease status: 449 days (1.2 years); Days to last follow up: 449 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: First line of therapy; Days to treatment start: 20 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Thalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 147 days; Days to treatment end: 208 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 211 days; Days to treatment end: 211 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 449.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 759 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 3.15 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 15.5 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 423 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.9 mmol/L; Albumin 37 g/L; Total Protein 7.04 g/dL; Glucose 6.82 mmol/L.
- Day 91 (ECOG 1): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 464 mg/dL; Immunoglobulin G 6 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 32.6 µg/mL; Lactate Dehydrogenase 9.59 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.12 ×10⁹/L; Absolute Neutrophil 1.69 ×10⁹/L; Platelets 78.5 ×10⁹/L; Creatinine 639 µmol/L; Blood Urea Nitrogen 2.78 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 5.54 g/dL; Glucose 8.2 mmol/L.
- Day 189 (ECOG 1): M Protein 7.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 86.3 mg/dL; Immunoglobulin G 9.4 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 4.73 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.62 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 847 µmol/L; Calcium 1.93 mmol/L; Albumin 29.9 g/L; Total Protein 5.12 g/dL; Glucose 14.6 mmol/L.
- Day 271 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.73 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 9.09 ×10⁹/L; Absolute Neutrophil 5.67 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 682 µmol/L; Calcium 2.23 mmol/L; Albumin 35.8 g/L; Total Protein 5.94 g/dL; Glucose 7.87 mmol/L.
- Day 355 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 2.78 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.32 ×10⁹/L; Absolute Neutrophil 4.19 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 753 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 35.3 g/L; Total Protein 5.09 g/dL; Glucose 12.3 mmol/L.
- Day 441 (ECOG 2): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1030 mg/dL; Immunoglobulin G 3.41 g/L; Immunoglobulin A 0.069 g/L; Immunoglobulin M 0.049 g/L; Hemoglobin 5.27 mmol/L; Leukocytes 5.86 ×10⁹/L; Absolute Neutrophil 4.99 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 863 µmol/L; Calcium 2.43 mmol/L; Albumin 30 g/L; Total Protein 5.23 g/dL; Glucose 10.1 mmol/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 174 cm.

Biospecimens (2 samples)
- Sample MMRF_2200_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2200_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
